Surgical pathology report (de-identified scan), TCGA case TCGA-CS-5397, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-5397-01A (Primary Tumor).

[page 1 of 3]
Patient:

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Left temporal lobe brain tumor (excision): anaplastic astrocytoma, grade III of IV (WHO scale), see microscopic description, see note
2. Left temporal lobe Brain tumor (excision): anaplastic astrocytoma, grade III of IV (WHO scale), see microscopic description, see note

Comment:

reviewed selected slides and concurs with the presence of malignancy in this material.

Report Electronically Signed on

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of a moderately pleomorphic and infiltrative proliferation of astrocytes. There are several mitoses. There is no microvascular proliferation and no necrosis. Focally, tumor cells are within the Virchow-Robin spaces. The findings are diagnostic of an anaplastic astrocytoma, grade III of IV (WHO scale).

Frozen Section Diagnosis:

1. Left temporal lobe tumor: Glial neoplasm -

Clinical History and Diagnosis:

[page 2 of 3]
[REDACTED]

None given

Source of Specimen:

- 1: Left temporal lobe tumor
- 2: Left temporal lobe tumor

Gross Description:

[REDACTED]

1. Left temporal lobe tumor: Received fresh for frozen section diagnosis, in a specimen container labeled with the patient's name and "1 left temporal lobe tumor" are multiple fragments of red-tan soft tissue measuring 2.5 x 1.0 x 1.0 cm in aggregate. Touch preparations are made, and 50% of the specimen submitted for frozen section diagnosis. The entire specimen is submitted as follows:

A. FSC

B. remainder of specimen

2. Left temporal lobe tumor: Received in formalin, in a specimen container labeled with the patient's name and "2 left temporal lobe tumor" are multiple fragments of tan-white soft tissue measuring 4.0 x 4.0 x 1.7 cm. The entire specimen is submitted in 7 cassettes..

Histology Laboratory

H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry,

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer' s recommendation.

Documented by [REDACTED] Vol

131, [REDACTED]

[page 3 of 3]
██████████
EGFR pharmDx Clone ██████████ Formalin fixed, paraffin embedded.
Interpretation follows the manufacturer's recommendation.

Documented by ██████████ Journal of Clinical Oncology
Vol 21 No. 20 ██████████

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the Clinical Laboratory of ██████████ Hospital.

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file d327f462-b3d0-4cbf-bbc0-d1149a824c33 (TCGA-CS-5397.7082A52B-E688-4642-9BCC-E9C0B2EAF79A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).